Somatic mutation profile of tumor specimen TCGA-44-3398-01A (aliquot TCGA-44-3398-01A-01D-1105-08) from TCGA case TCGA-44-3398, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 77.7 years (28,392 days).
Specimen TCGA-44-3398-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32131c87-c7db-41cc-990c-f62e1788ad0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-3398-10A (Blood Derived Normal), aliquot TCGA-44-3398-10A-01D-1105-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04b50865-c367-44be-8288-3c5464135074

The open-access MAF lists 194 somatic variants for this specimen: 143 protein-altering or splice-affecting, 46 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 126, Silent 46, Nonsense Mutation 10, Splice Site 3, Frame Shift Del 2, RNA 2, Intron 2, Frame Shift Ins 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAK1 | c.2111C>G p.S704C | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV68646989; called by muse, mutect2
- ABLIM3 | c.987T>A p.Y329* | Nonsense Mutation (SNP) | VAF 44/208 reads (21%) | catalogued as COSV58649449; called by muse, mutect2, varscan2
- ACVR2B | c.1345-1G>T p.X449_splice | Splice Site (SNP) | VAF 46/549 reads (8%) | catalogued as COSV61704019; called by muse, mutect2
- ADAM12 | c.2557C>A p.P853T | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1248558182, COSV64138190; called by muse, mutect2
- ADAMTS4 | c.1607G>A p.C536Y | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775557044, COSV63491350; called by muse, mutect2
- AKAP4 | c.1303A>T p.I435L | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62075648; called by muse, mutect2
- ALKBH4 | c.307G>C p.G103R | Missense Mutation (SNP) | VAF 14/317 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52962441; called by muse, mutect2
- AMER1 | c.2078C>G p.P693R | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV57670153; called by muse, mutect2, varscan2
- AMER1 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs1394216535, COSV57670168; called by muse, mutect2
- ANO10 | c.1865T>A p.M622K | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV52736921; called by muse, mutect2
- ARHGEF28 | c.2209G>T p.V737L | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV55272031; called by muse, mutect2
- ARRB2 | c.708G>A p.V236= | Splice Region (SNP) | VAF 24/346 reads (7%) | catalogued as COSV52618331; called by muse, mutect2
- ATP13A1 | c.2581_2582del p.M861Vfs*15 | Frame Shift Del (DEL) | VAF 5/45 reads (11%) | catalogued as rs769337789; called by mutect2, varscan2
- BAG3 | c.827G>T p.R276L | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100958234; called by muse, mutect2, varscan2
- BCHE | c.1398T>A p.H466Q | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1289157673, COSV100012564; called by muse, mutect2
- BICRAL | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 31/344 reads (9%) | catalogued as COSV58405607, COSV58408759; called by muse, mutect2
- BRINP2 | c.1903T>A p.W635R | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as COSV64180755; called by muse, mutect2, varscan2
- BTK | c.582G>T p.E194D | Missense Mutation (SNP) | VAF 19/191 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV58124184; called by muse, mutect2, varscan2
- CACNA2D1 | c.1666C>A p.P556T (on ENST00000356253 / NM_001366867.1; = p.P537T on NM_000722.4) | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV62394502; called by muse, mutect2, varscan2
- CACNA2D4 | c.1751C>A p.P584H | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54962385; called by muse, mutect2
- CASC3 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV52868652; called by muse, mutect2
- CCDC181 | c.1153G>C p.E385Q | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV63158354; called by muse, mutect2
- CCKBR | c.209G>C p.G70A | Missense Mutation (SNP) | VAF 15/215 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as COSV58106358; called by muse, mutect2
- CD33 | c.270C>A p.F90L | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51805365; called by muse, mutect2
- CD82 | c.158G>C p.R53T | Missense Mutation (SNP) | VAF 15/288 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV57037751; called by muse, mutect2
- CDH10 | c.2292C>G p.Y764* | Nonsense Mutation (SNP) | VAF 59/257 reads (23%) | catalogued as COSV100052840, COSV52600483; called by muse, mutect2, varscan2
- CELF1 | c.108C>G p.F36L | Missense Mutation (SNP) | VAF 19/229 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.967); catalogued as COSV60113490, COSV60116284; called by muse, mutect2
- CEP85L | c.172A>T p.S58C | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63829189; called by muse, mutect2, varscan2
- CLCA2 | c.134T>A p.I45N | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV65288997; called by muse, mutect2, varscan2
- CMTR2 | c.1451G>C p.G484A | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as COSV57605238; called by muse, mutect2, varscan2
- COL25A1 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV67660032; called by muse, mutect2, varscan2
- COL4A6 | c.4852C>A p.L1618M | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57880272; called by muse, varscan2
- CSMD2 | c.4021G>C p.E1341Q | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV53969766; called by muse, mutect2
- CUL7 | c.4252C>G p.L1418V | Missense Mutation (SNP) | VAF 9/276 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54822717; called by muse, mutect2
- CXXC1 | c.1314G>C p.Q438H | Missense Mutation (SNP) | VAF 8/234 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as rs1210340261, COSV53277200; called by muse, mutect2
- D2HGDH | c.363G>C p.E121D | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as COSV58323724; called by muse, mutect2, varscan2
- DCAF11 | c.172G>T p.V58L | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.037); catalogued as rs1440991756, COSV58110934; called by muse, mutect2, varscan2
- DHX34 | c.1685G>T p.R562L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV60898622; called by muse, mutect2, varscan2
- DNAH3 | c.4327G>A p.A1443T | Missense Mutation (SNP) | VAF 30/252 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54556738; called by muse, mutect2, varscan2
- DST | c.17257G>C p.D5753H (on ENST00000361203 / NM_001374722.1; = p.D3450H on NM_015548.5) | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1411497493, COSV55043981; called by muse, mutect2
- DST | c.10459T>A p.S3487T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV99756294; called by muse, mutect2
- EIF4G3 | c.742G>T p.G248C | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.873); catalogued as COSV51695540; called by muse, mutect2, varscan2
- ELFN2 | c.200T>G p.L67R | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV68746839; called by muse, mutect2
- ENSA | c.151T>G p.S51A | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99651354; called by muse, mutect2
- ETV6 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56766946; called by muse, mutect2
- EXPH5 | c.5102A>T p.N1701I | Missense Mutation (SNP) | VAF 35/350 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as COSV56209132; called by muse, mutect2, varscan2
- FAAH | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as rs1014010846, COSV54546263; called by muse, mutect2, varscan2
- FAM83G | c.1967G>A p.R656Q | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs768311912, COSV58762723; called by muse, mutect2
- FLI1 | c.1259C>T p.S420L | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV55648283; called by muse, mutect2
- FRMPD1 | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 16/119 reads (13%) | catalogued as COSV66703578; called by muse, mutect2, varscan2
- GCM2 | c.1382T>A p.V461E | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV65276736; called by muse, mutect2, varscan2
- GJA10 | c.1114A>C p.T372P | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.157); catalogued as COSV65356493; called by muse, mutect2, varscan2
- HAUS4 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 16/366 reads (4%) | catalogued as COSV52828451; called by muse, mutect2
- HMBS | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 19/208 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53830410; called by muse, mutect2
- IGSF1 | c.3554G>T p.G1185V | Missense Mutation (SNP) | VAF 46/496 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV63835825, COSV63840811; called by muse, mutect2
- IRS4 | c.1336C>A p.P446T | Missense Mutation (SNP) | VAF 28/300 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV64536270; called by muse, mutect2
- ITGA1 | c.1744A>C p.N582H | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50901591; called by muse, mutect2
- ITGA2 | c.2767G>A p.D923N | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); catalogued as COSV56867398; called by muse, mutect2
- KALRN | c.3581T>A p.L1194Q | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53782067; called by muse, mutect2, varscan2
- KCNA1 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 41/402 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66836887, COSV66837092, COSV66838766; called by muse, mutect2, varscan2
- KIAA0100 | c.3674A>C p.H1225P | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV66496913; called by muse, mutect2, varscan2
- KIAA1210 | c.71A>G p.Y24C | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV68180612; called by muse, mutect2, varscan2
- KIAA1755 | c.818G>T p.G273V | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54074106, COSV54081414; called by muse, mutect2
- KIF4B | c.3584C>T p.S1195L | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1415310652, COSV70531844; called by muse, mutect2, varscan2
- KRTAP13-3 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV61880545; called by muse, mutect2, varscan2
- LILRA2 | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 24/394 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs770183945, COSV52191773; called by muse, mutect2
- LPAR4 | c.9C>A p.D3E | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV70913554; called by muse, mutect2
- LRP1B | c.8620C>A p.H2874N | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.055); catalogued as COSV101257402; called by muse, mutect2
- LRP1B | c.8619C>A p.D2873E | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101257404; called by muse, mutect2
- LRRIQ1 | c.1661A>T p.Q554L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV67839716; called by muse, mutect2, varscan2
- LVRN | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63498610; called by muse, mutect2
- MAGEB1 | c.826G>C p.A276P | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100974981; called by muse, mutect2, varscan2
- MAP9 | c.983C>A p.T328K | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.747); catalogued as COSV60906792; called by muse, mutect2
- MAPK15 | c.268C>A p.L90M | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62030623; called by muse, mutect2
- METTL4 | c.379A>G p.I127V | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV55249991; called by muse, mutect2
- MRE11 | c.616G>T p.D206Y | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as COSV60581060; called by muse, mutect2
- MTOR | c.6617A>G p.N2206S | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63879105; called by muse, mutect2, varscan2
- MTOR | c.2573A>G p.Y858C | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63879113; called by muse, mutect2, varscan2
- MUC16 | c.42916G>A p.E14306K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.879); catalogued as COSV66697269; called by muse, mutect2, varscan2
- MYH13 | c.5395C>A p.H1799N | Missense Mutation (SNP) | VAF 36/358 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV52844806; called by muse, mutect2, varscan2
- MYH2 | c.3656T>C p.V1219A | Missense Mutation (SNP) | VAF 30/243 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.644); catalogued as COSV55450111; called by muse, mutect2, varscan2
- NKD1 | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs775680781, COSV51695099; called by muse, mutect2
- NXF5 | n.1280-2A>T | Splice Site (SNP) | VAF 31/227 reads (14%) | catalogued as COSV53791558, COSV53793819; called by muse, mutect2, varscan2
- OR2A14 | c.274T>A p.S92T | Missense Mutation (SNP) | VAF 55/569 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs1027163962, COSV68718767; called by muse, mutect2, varscan2
- OR4C15 | c.140C>A p.A47D | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100115286, COSV58956157; called by muse, mutect2
- OR5B12 | c.586G>T p.V196F | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.16); catalogued as rs750113374, COSV56905488, COSV56906969; called by muse, mutect2, varscan2
- OR5L2 | c.454G>T p.G152W | Missense Mutation (SNP) | VAF 32/256 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65725354; called by muse, mutect2, varscan2
- OXER1 | c.1058T>A p.V353E | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54310303, COSV54313464; called by muse, mutect2
- PALB2 | c.1958G>T p.C653F | Missense Mutation (SNP) | VAF 29/285 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.325); catalogued as rs771246748, COSV55170933; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCNX4 | c.421G>C p.V141L | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV100470371; called by muse, mutect2
- PHLDB2 | c.2675G>T p.G892V (on ENST00000393925 / NM_001134439.2; = p.G849V on NM_145753.2) | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV67316584; called by muse, mutect2, varscan2
- PJA1 | c.1253G>T p.G418V (on ENST00000361478 / NM_145119.4; = p.G230V on NM_022368.5) | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV64053860; called by muse, mutect2
- PLEC | c.13249G>A p.V4417M (on ENST00000322810 / NM_201380.4; = p.V4307M on NM_000445.5) | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as rs1408053127, COSV59702297; called by muse, mutect2, varscan2
- POSTN | c.1654C>G p.L552V | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65712346, COSV65714933; called by muse, mutect2
- PRDM2 | c.722C>A p.T241N | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.01); catalogued as COSV52456843; called by muse, mutect2
- PRDX4 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.16); catalogued as COSV65018603, COSV65018868; called by muse, mutect2
- PRORP | c.1425-2A>T p.X475_splice | Splice Site (SNP) | VAF 18/176 reads (10%) | catalogued as COSV51623707; called by muse, mutect2, varscan2
- PSG4 | c.865C>G p.P289A | Missense Mutation (SNP) | VAF 38/540 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.528); catalogued as rs530827336, COSV54941853; called by muse, mutect2
- PSG4 | c.429C>A p.H143Q | Missense Mutation (SNP) | VAF 62/405 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV54941863; called by muse, varscan2
- RBBP5 | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 38/390 reads (10%) | catalogued as COSV52707161; called by muse, mutect2
- RBM47 | c.1481C>T p.A494V (on ENST00000295971 / NM_001098634.2; = p.A425V on NM_019027.4) | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.196); catalogued as COSV55944284, COSV99920497; called by muse, mutect2, varscan2
- RYR1 | c.5009G>A p.R1670H | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.771); catalogued as rs1248039154, COSV62107618; ClinVar: uncertain significance; called by muse, varscan2
- SCNN1B | c.961C>G p.H321D | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56307150, COSV56310976; called by muse, mutect2, varscan2
- SEC24D | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 24/349 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); catalogued as rs754536468, COSV54885576; called by muse, mutect2
- SEMA3C | c.1316C>A p.A439D | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54857073; called by muse, mutect2
- SPANXN5 | c.116G>A p.S39N | Missense Mutation (SNP) | VAF 18/195 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1390543569, COSV64968902; called by muse, mutect2
- SRPX2 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs1260161778, COSV65933759; called by muse, mutect2
- ST8SIA1 | c.413G>T p.C138F | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99683183; called by muse, mutect2
- SUSD5 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0.017); catalogued as rs1234070467, COSV58880204; called by muse, mutect2
- SYNE2 | c.19684G>T p.A6562S | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV59972680; called by muse, mutect2, varscan2
- SYP | c.909G>C p.Q303H | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99602916; called by muse, mutect2, varscan2
- TAF4 | c.1522G>T p.A508S | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.091); catalogued as COSV53343927; called by muse, mutect2, varscan2
- TAZ | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); catalogued as COSV50011364; called by muse, mutect2
- TCF20 | c.713C>G p.S238C | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as rs200443690, COSV59496644; called by muse, mutect2
- TMEM176B | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV50245722, COSV99134045; called by muse, mutect2, varscan2
- TMEM200A | c.567G>T p.M189I | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV51660646, COSV99759845; called by muse, mutect2, varscan2
- TNN | c.3822C>G p.I1274M | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53437210; called by muse, mutect2
- TOB2 | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 17/194 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as COSV100548428, COSV59500503; called by muse, mutect2
- TOPORS | c.2865A>G p.I955M | Missense Mutation (SNP) | VAF 25/234 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.157); catalogued as COSV62118433; called by muse, mutect2, varscan2
- TRPC3 | c.586A>T p.N196Y (on ENST00000379645 / NM_001366479.2; = p.N123Y on NM_003305.2) | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV53382323; called by muse, mutect2
- TRPS1 | c.2641G>A p.E881K (on ENST00000220888 / NM_001330599.2; = p.E894K on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV55265024; called by muse, mutect2
- TRPV5 | c.2066C>A p.S689Y | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1487464735, COSV54690493; called by muse, mutect2
- TSHZ3 | c.2662G>A p.A888T | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs547631684, COSV53668533; called by muse, mutect2, varscan2
- TTC38 | c.472C>T p.Q158* | Nonsense Mutation (SNP) | VAF 23/221 reads (10%) | catalogued as COSV66844060, COSV66845339; called by muse, mutect2
- UBAP2 | c.1270G>T p.D424Y | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV62549328; called by muse, mutect2, varscan2
- USH1G | c.934C>A p.L312M | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58883972; called by muse, mutect2
- WDR5B | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 28/242 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100413112; called by muse, mutect2, varscan2
- ZBED4 | c.116G>C p.R39T | Missense Mutation (SNP) | VAF 12/374 reads (3%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV104369438, COSV53468557; called by muse, mutect2
- ZC3H13 | c.4411G>A p.E1471K (on ENST00000242848 / NM_001330565.2; = p.E1472K on NM_015070.6) | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV54452441, COSV54464821; called by muse, mutect2
- ZNF135 | c.794C>A p.T265N (on ENST00000313434 / NM_001289401.2; = p.T277N on NM_003436.4) | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV57886489; called by muse, mutect2, varscan2
- ZNF318 | c.478A>T p.S160C | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV58592545; called by muse, mutect2, varscan2
- ZNF407 | c.5565G>T p.R1855S | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV55241475, COSV55272492; called by muse, mutect2, varscan2
- ZNF438 | c.1959G>T p.Q653H | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV59201530; called by muse, mutect2
- ZNF667 | c.1750G>C p.E584Q | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.181); catalogued as COSV52640044; called by muse, mutect2
- ZNF800 | c.535A>T p.K179* | Nonsense Mutation (SNP) | VAF 17/138 reads (12%) | catalogued as COSV56180465; called by muse, mutect2, varscan2
- ZNF804A | c.2624T>G p.L875* | Nonsense Mutation (SNP) | VAF 21/135 reads (16%) | catalogued as COSV56474204; called by muse, mutect2, varscan2
- ZXDB | c.2050G>A p.A684T | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV100885932; called by muse, mutect2
- GGNBP2 | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- IGHM | c.1239C>G p.C413W | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- PTEN | c.21dup p.I8Dfs*3 | Frame Shift Ins (INS) | VAF 18/146 reads (12%) | called by mutect2, pindel, varscan2
- USP34 | c.327_330del p.R109Sfs*13 | Frame Shift Del (DEL) | VAF 19/188 reads (10%) | called by mutect2, pindel, varscan2
- XAGE2 | c.319G>T p.G107W | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XAGE2 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADGRE1 | c.2250C>T p.F750= | Silent (SNP) | VAF 24/372 reads (6%) | catalogued as COSV51674251; called by muse, mutect2
- AIDA | c.885T>A p.L295= | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as COSV60518722; called by muse, mutect2
- AKAP4 | c.1305A>T p.I435= | Silent (SNP) | VAF 24/250 reads (10%) | catalogued as COSV62075639; called by muse, mutect2
- AL136295.1 | c.12C>G p.L4= | Silent (SNP) | VAF 14/128 reads (11%) | catalogued as COSV51662115, COSV99164580; called by muse, mutect2, varscan2
- BPIFB2 | c.1023G>T p.V341= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV50071802; called by muse, mutect2, varscan2
- CASP5 | c.591C>T p.I197= | Silent (SNP) | VAF 22/211 reads (10%) | catalogued as COSV52830794, COSV52832297; called by muse, mutect2, varscan2
- CENPF | c.285A>G p.S95= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV65279688; called by mutect2, varscan2
- CHD6 | c.4323C>T p.L1441= | Silent (SNP) | VAF 8/130 reads (6%) | catalogued as COSV64695137; called by muse, mutect2
- CNOT2 | c.1593C>T p.F531= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV57507530; called by muse, mutect2
- CRYBA4 | c.327C>A p.I109= | Silent (SNP) | VAF 19/153 reads (12%) | catalogued as COSV61322026; called by muse, mutect2, varscan2
- DARS2 | c.1458C>G p.L486= | Silent (SNP) | VAF 21/182 reads (12%) | catalogued as COSV53409522; called by muse, mutect2, varscan2
- DNAH10 | c.4893C>T p.F1631= (on ENST00000409039; = p.F1570= on NM_207437.3) | Silent (SNP) | VAF 10/262 reads (4%) | catalogued as rs776446148, COSV68987845; called by muse, mutect2
- DOCK2 | c.732C>G p.L244= | Silent (SNP) | VAF 19/253 reads (8%) | catalogued as COSV56963557, COSV56992045, COSV99910029; called by muse, mutect2
- FEZF1 | c.1305C>T p.G435= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as COSV58659856; called by muse, mutect2
- FUZ | c.372G>A p.L124= | Silent (SNP) | VAF 59/1092 reads (5%) | catalogued as COSV58243216; called by muse, mutect2
- GPLD1 | c.858A>G p.A286= | Silent (SNP) | VAF 21/197 reads (11%) | catalogued as COSV57761614, COSV57761964; called by muse, mutect2, varscan2
- IGHV1-46 | c.183A>G p.G61= | Silent (SNP) | VAF 16/173 reads (9%) | called by muse, mutect2
- IL27RA | c.555C>A p.T185= | Silent (SNP) | VAF 31/390 reads (8%) | catalogued as COSV54603528; called by muse, mutect2
- KCNJ3 | c.741C>T p.D247= | Silent (SNP) | VAF 6/93 reads (6%) | catalogued as COSV54545799; called by muse, mutect2
- LAMA4 | c.2133A>G p.R711= (on ENST00000230538 / NM_001105206.3; = p.R704= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as COSV57905944; called by muse, mutect2, varscan2
- MAP3K4 | c.2688C>T p.L896= | Silent (SNP) | VAF 29/134 reads (22%) | catalogued as rs1301108508, COSV62339251; called by muse, mutect2, varscan2
- MED12 | c.663C>A p.P221= | Silent (SNP) | VAF 22/219 reads (10%) | catalogued as COSV61358083; called by muse, mutect2
- MTAP | c.429G>A p.P143= | Silent (SNP) | VAF 42/351 reads (12%) | catalogued as rs751428352, COSV66477154; called by muse, mutect2, varscan2
- MUC16 | c.10980A>G p.E3660= | Silent (SNP) | VAF 9/136 reads (7%) | catalogued as COSV67498667; called by muse, mutect2
- NAGA | c.726G>A p.V242= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV67170405; called by mutect2, varscan2
- NLRP2 | c.120G>A p.Q40= | Silent (SNP) | VAF 10/162 reads (6%) | catalogued as rs1412888567, COSV54759407; called by muse, mutect2
- NLRP4 | c.2457G>T p.L819= | Silent (SNP) | VAF 19/157 reads (12%) | catalogued as COSV56720650, COSV56724684; called by muse, mutect2, varscan2
- NPBWR2 | c.486G>T p.G162= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV63900679; called by muse, mutect2, varscan2
- OLFML2B | c.945G>A p.E315= | Silent (SNP) | VAF 18/208 reads (9%) | catalogued as COSV54200882; called by muse, mutect2
- OR10H5 | c.36C>T p.F12= | Silent (SNP) | VAF 17/374 reads (5%) | catalogued as COSV100454714; called by muse, mutect2
- OR5D16 | c.789A>G p.V263= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as rs558830271, COSV65723099; called by muse, mutect2, varscan2
- OR5M11 | c.579C>G p.V193= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV101602044; called by muse, mutect2, varscan2
- PCDH11X | c.3000C>A p.T1000= | Silent (SNP) | VAF 28/259 reads (11%) | catalogued as COSV53509930; called by muse, mutect2, varscan2
- PCDHGB2 | c.1581C>T p.A527= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV54046372; called by muse, mutect2, varscan2
- PHLPP1 | c.4782C>T p.G1594= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV53040290; called by muse, mutect2, varscan2
- RHOD | c.252G>T p.L84= | Silent (SNP) | VAF 37/328 reads (11%) | catalogued as COSV58212105; called by muse, mutect2, varscan2
- SEMA6B | c.138C>T p.P46= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV100015139, COSV56702412; called by muse, mutect2, varscan2
- ST8SIA1 | c.414C>T p.C138= | Silent (SNP) | VAF 20/206 reads (10%) | catalogued as rs373672934; called by muse, mutect2
- TNR | c.726G>T p.R242= | Silent (SNP) | VAF 19/169 reads (11%) | catalogued as COSV54900293, COSV54920439; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1194C>G p.V398= | Silent (SNP) | VAF 7/133 reads (5%) | catalogued as COSV54652542; called by muse, mutect2
- TSPYL4 | c.1119C>T p.I373= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100126732; called by muse, mutect2, varscan2
- TTC14 | c.501A>G p.L167= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as COSV56011509, COSV56014555; called by muse, mutect2, varscan2
- TTLL2 | c.258G>T p.P86= | Silent (SNP) | VAF 20/132 reads (15%) | catalogued as COSV53446206; called by muse, mutect2, varscan2
- UBOX5 | c.510G>T p.V170= | Silent (SNP) | VAF 16/180 reads (9%) | catalogued as COSV53910176; called by muse, mutect2
- ZC3H13 | c.1374G>C p.R458= | Silent (SNP) | VAF 16/294 reads (5%) | catalogued as COSV54464840; called by muse, mutect2
- ZNF672 | c.1350T>A p.S450= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- FOLH1B | n.1617G>T | RNA (SNP) | VAF 8/85 reads (9%) | called by muse, mutect2, varscan2
- HLA-DRB9 | n.268C>T | RNA (SNP) | VAF 22/160 reads (14%) | called by muse, mutect2, varscan2
- OR52A4P | chr11:5121002 C>A | 3'Flank (SNP) | VAF 12/93 reads (13%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+2029G>T | Intron (SNP) | VAF 20/226 reads (9%) | catalogued as COSV100314306; called by muse, mutect2
- WDR44 | c.112-919G>T | Intron (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99561563; called by muse, mutect2
